EXCEPTIONAL_RESPONDERS case ER-AE02 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and ill-defined digestive organs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f2d36b3e-5bd6-4c30-ab29-c21fe2547d0e

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1946; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Gastrointestinal tract, NOS; Site of resection or biopsy: Gastrointestinal tract, NOS; Classification of tumor: primary; Age at diagnosis: 65.4 years (23,888 days); Year of diagnosis: 2012; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,562 days (4.3 years); Days to best overall response: 336 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Epirubicin Hydrochloride; Days to treatment start: 39 days; Days to treatment end: 144 days.
   Treatment given: Therapeutic agents: Oxaliplatin; Days to treatment start: 39 days; Days to treatment end: 403 days (1.1 years).
   Treatment given: Therapeutic agents: Capecitabine; Days to treatment start: 179 days; Days to treatment end: 403 days (1.1 years).

Follow-up (1 entry)
- Days to follow up: 1,562 days (4.3 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 1,562 days (4.3 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AE02-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE02-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
